Somatic mutation profile of tumor specimen TCGA-BR-8592-01A (aliquot TCGA-BR-8592-01A-11D-2394-08) from TCGA case TCGA-BR-8592, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 63.3 years (23,133 days).
Specimen TCGA-BR-8592-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 638f1c19-73be-4b22-9e1d-8dfd759d5502.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8592-10A (Blood Derived Normal), aliquot TCGA-BR-8592-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e89b5d4e-55c0-42fe-9c3f-44fb01c5e20d

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55731958; called by muse, mutect2
- ADRA1A | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs771422009, COSV52370758; called by muse, mutect2
- CHD7 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); catalogued as rs368934543; called by muse, mutect2
- CR1 | c.3746A>C p.E1249A | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65461401; called by muse, mutect2
- CTCF | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1567610917, COSV50461678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERICH3 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as rs368878615; called by muse, mutect2, varscan2
- GPR179 | c.638A>G p.K213R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs201661414; called by muse, mutect2, varscan2
- GRIK1 | c.1974C>A p.F658L | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58727306; called by muse, mutect2
- KRT86 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV53292648; called by muse, mutect2
- MC3R | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as rs778979632, COSV54763896; called by muse, mutect2
- MTMR12 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53786457; called by muse, mutect2, varscan2
- MYH10 | c.1963C>A p.Q655K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52607360; called by muse, mutect2, varscan2
- NKAP | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs776850287, COSV65056726; called by muse, mutect2, varscan2
- NLRP5 | c.3185C>T p.S1062L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs761657995, COSV66761912; called by muse, mutect2
- OR4M1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.367); catalogued as rs201377742, COSV100270969, COSV60060509; called by muse, mutect2, varscan2
- PAK3 | c.619G>A p.A207T (on ENST00000262836 / NM_001324328.2; = p.A192T on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as rs1029470602, COSV53278411, COSV53282300; called by muse, varscan2
- PCDHA2 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.08); catalogued as COSV65369662; called by muse, mutect2, varscan2
- PLAG1 | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.778); catalogued as COSV57613839; called by muse, mutect2
- PLXNC1 | c.2642T>C p.L881P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV51580582; called by muse, mutect2
- RPL22 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV52378791; called by muse, mutect2, varscan2
- TENM1 | c.5572A>G p.T1858A | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as rs1434368498, COSV64431044, COSV64439111; called by muse, mutect2, varscan2
- ZNF536 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100835449, COSV62830708; called by muse, mutect2
- PIGR | c.1008dup p.S337Lfs*12 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- C3orf20 | c.780G>A p.P260= | Silent (SNP) | VAF 15/172 reads (9%) | catalogued as rs758248068, COSV53783319; called by muse, mutect2
- COL22A1 | c.2163C>A p.V721= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV57351745; called by muse, mutect2, varscan2
- SLC32A1 | c.1071C>T p.V357= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV54147850; called by muse, mutect2
- TNXB | c.4062C>T p.P1354= (on ENST00000647633; = p.P1107= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs1443329191, COSV64485407; called by muse, mutect2
- TSPAN7 | c.9G>A p.S3= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs758032272, COSV54533179; called by muse, varscan2
- ZP1 | c.1213C>T p.L405= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as COSV53925812; called by muse, mutect2
- SNORD116-21 | n.81G>T | RNA (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
